Somatic mutation profile of tumor specimen TCGA-KN-8424-01A (aliquot TCGA-KN-8424-01A-11D-2310-10) from TCGA case TCGA-KN-8424, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 42.1 years (15,384 days).
Specimen TCGA-KN-8424-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff282c0d-c6dc-4237-ac00-6cb9d18c7873.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8424-11A (Solid Tissue Normal), aliquot TCGA-KN-8424-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3aa1bd9-7d79-43cc-b9f3-075292396ae4

The open-access MAF lists 31 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 3, 3'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); catalogued as rs121912664, CM012663, CM104660, COSV52665150, COSV52691988, COSV52828545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 14/52 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRD1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs745528936, COSV99349444; called by muse, mutect2, varscan2
- ERBB4 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 58/88 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53527146; called by muse, mutect2, varscan2
- GZMK | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 30/104 reads (29%) | catalogued as rs1202037290; called by muse, mutect2, varscan2
- KRR1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99875474; called by muse, mutect2, varscan2
- NEDD4L | c.2884C>T p.L962F (on ENST00000400345 / NM_001144967.3; = p.L942F on NM_015277.6) | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.748); catalogued as rs1568964410, COSV99894021; called by muse, mutect2, varscan2
- OR6N2 | c.893T>C p.I298T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV59411045; called by muse, mutect2, varscan2
- UNC13D | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs757643349, COSV99255952; called by muse, mutect2, varscan2
- WNT2B | c.988A>G p.K330E (on ENST00000369684 / NM_024494.3; = p.K311E on NM_004185.4) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0.099); catalogued as COSV56675766; called by muse, mutect2, varscan2
- ADCK5 | c.1063G>A p.G355S | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRS3 | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CCDC62 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- CLCA1 | c.1280A>T p.Q427L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- HSP90AB1 | c.964T>G p.S322A | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- JMJD1C | c.5562dup p.N1855* | Frame Shift Ins (INS) | VAF 22/91 reads (24%) | called by mutect2, pindel, varscan2
- LRP2 | c.7739T>C p.L2580P | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- MDC1 | c.4816G>T p.V1606F | Missense Mutation (SNP) | VAF 69/111 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- NGRN | c.710dup p.Y237* | Nonsense Mutation (INS) | VAF 16/81 reads (20%) | called by mutect2, varscan2
- SCFD1 | c.394A>G p.N132D | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SHROOM2 | c.3640A>G p.I1214V | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TMPRSS15 | c.326C>A p.S109* | Nonsense Mutation (SNP) | VAF 42/158 reads (27%) | called by muse, mutect2, varscan2
- TNS3 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 32/146 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- CBARP | c.60G>A p.S20= (on ENST00000382477; = p.S26= on NM_152769.3) | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as rs1177955369; called by muse, mutect2, varscan2
- CYP2E1 | c.762T>C p.H254= | Silent (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- FGL2 | c.552C>T p.V184= | Silent (SNP) | VAF 68/135 reads (50%) | catalogued as rs776444180; called by muse, mutect2, varscan2
- KIRREL1 | c.636G>A p.E212= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- MON2 | c.3483A>T p.V1161= | Silent (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- SCRIB | c.4686G>A p.P1562= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs782007188, COSV100252416; called by mutect2, varscan2
- C1orf74 | c.*3367G>A | 3'UTR (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99160021; called by muse, mutect2, varscan2
- FUT2 | c.*266G>A | 3'UTR (SNP) | VAF 11/70 reads (16%) | catalogued as COSV101218000; called by muse, mutect2
